Somatic mutation profile of tumor specimen TCGA-DQ-5630-01A (aliquot TCGA-DQ-5630-01A-01D-1870-08) from TCGA case TCGA-DQ-5630, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 73.5 years (26,855 days).
Specimen TCGA-DQ-5630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54829888-c6bc-47f6-82f3-353217a07f48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-5630-10A (Blood Derived Normal), aliquot TCGA-DQ-5630-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85019964-4878-49b7-9772-ffd00bf414df

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008654; called by muse, mutect2
- AGAP1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs767569690, COSV100367099; called by muse, mutect2, varscan2
- ANK3 | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV99782375; called by muse, mutect2, varscan2
- ARID1A | c.2405A>C p.Q802P | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100253454; called by muse, mutect2, varscan2
- B4GALNT4 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as rs1311621009, COSV57321443, COSV57322682; called by muse, mutect2, varscan2
- BRD3 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325542; called by muse, mutect2
- CELSR2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.937); catalogued as COSV99602965, COSV99603988; called by muse, mutect2, varscan2
- DBNL | c.1288G>C p.E430Q (on ENST00000448521 / NM_001014436.3; = p.E431Q on NM_014063.7) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99033095, COSV99803913; called by muse, mutect2, varscan2
- DNAH1 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs759820286, COSV70231810; called by mutect2, varscan2
- DOCK4 | c.5815C>T p.R1939* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as rs527410636, COSV101447983; called by muse, mutect2, varscan2
- DST | c.4741G>C p.D1581H | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99760014; called by muse, mutect2
- ELF5 | c.188A>G p.Y63C (on ENST00000312319 / NM_198381.2; = p.Y53C on NM_001422.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV56628799; called by muse, mutect2, varscan2
- ETNK2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs759671962, COSV65820568; called by muse, mutect2, varscan2
- FEZF1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as rs757482017, COSV100484559; called by muse, mutect2, varscan2
- GRB10 | c.1256C>T p.P419L (on ENST00000398812; = p.P373L on NM_001001549.3) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs763393579; called by muse, mutect2, varscan2
- H2AC1 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs373261344, COSV51238948; called by muse, mutect2, varscan2
- HEPHL1 | c.182T>G p.L61* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100244420; called by muse, mutect2
- HFM1 | c.495-1G>C p.X165_splice | Splice Site (SNP) | VAF 5/75 reads (7%) | catalogued as COSV54027486, COSV99646818; called by muse, mutect2
- HTR1B | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV100885485; called by muse, mutect2
- JCAD | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV100948574; called by muse, mutect2, varscan2
- KCNJ8 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs776710700, COSV53716317; called by muse, mutect2, varscan2
- KCNK15 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.937); catalogued as COSV100865216; called by muse, mutect2, varscan2
- KIRREL2 | c.1511-1G>T p.X504_splice | Splice Site (SNP) | VAF 23/181 reads (13%) | catalogued as COSV99384447; called by muse, mutect2, varscan2
- LAIR1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs184253479, COSV100479893, COSV57305728; called by muse, mutect2, varscan2
- LARP4 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1181739914, COSV99529686; called by muse, mutect2, varscan2
- LCP1 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.382); catalogued as COSV100550079; called by muse, mutect2, varscan2
- LILRB1 | c.671G>T p.S224I (on ENST00000427581; = p.S188I on NM_006669.6) | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); catalogued as rs1463646594, COSV100207894; called by muse, mutect2, varscan2
- LONP2 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as COSV99589521; called by muse, mutect2, varscan2
- MED23 | c.3227T>C p.V1076A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV100645401; called by muse, varscan2
- MFSD14B | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100942801; called by muse, mutect2
- MYH10 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99346374; called by muse, mutect2
- NEUROD6 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | catalogued as COSV51769347, COSV51770836; called by muse, mutect2, varscan2
- NOP58 | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV99970845; called by muse, mutect2
- OR5AC2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs565646972, COSV62279069; called by muse, mutect2, varscan2
- OR8I2 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV100136265, COSV56168115; called by muse, mutect2, varscan2
- OSBPL8 | c.2473A>G p.I825V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1000453145, COSV99675601; called by muse, mutect2, varscan2
- PARP14 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV101506350; called by muse, mutect2, varscan2
- PIK3CA | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV55877747, COSV55879903; called by muse, mutect2, varscan2
- PXDNL | c.2147C>A p.P716Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV100686391; called by muse, mutect2, varscan2
- SH3BP4 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.474); catalogued as rs748959328, COSV100749313; called by muse, mutect2, varscan2
- SLC2A10 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs1255070229, COSV63713604; called by muse, mutect2
- SORT1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56666474, COSV99861133; called by muse, mutect2
- STX11 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.144); catalogued as rs765607265, COSV100845530; called by mutect2, varscan2
- TBC1D2B | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs753521405, COSV100317761; called by muse, mutect2, varscan2
- TOPBP1 | c.4392G>C p.L1464F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53438817, COSV99605837; called by muse, mutect2
- TRIM22 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372042006, COSV66090849; called by muse, mutect2
- XPNPEP3 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100846834; called by muse, mutect2
- ZFP37 | c.27T>G p.I9M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100953336; called by muse, mutect2, varscan2
- CELSR2 | c.2214_2216del p.D738del | In Frame Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- GPM6B | c.336_338del p.T113del | In Frame Del (DEL) | VAF 18/92 reads (20%) | called by pindel, varscan2
- TP53 | c.960_978del p.K320Nfs*19 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel
- TTN | c.22410_22414del p.S7471Qfs*14 (on ENST00000591111; = p.S6544Qfs*14 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel
- ACAT2 | c.1041G>A p.G347= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV100365074; called by muse, mutect2, varscan2
- ASTN1 | c.1221T>A p.P407= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99923077; called by muse, mutect2, varscan2
- CASP8AP2 | c.5301A>T p.I1767= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99387569; called by muse, mutect2, varscan2
- EPB41L2 | c.1737T>C p.P579= | Silent (SNP) | VAF 9/180 reads (5%) | catalogued as rs1454724998; called by muse, mutect2
- FGF2 | c.648G>A p.L216= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99144719; called by muse, mutect2
- GRHL2 | c.999C>T p.D333= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV99307818; called by muse, mutect2
- IL1R2 | c.915C>T p.Y305= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100208262; called by muse, mutect2
- INSM2 | c.708C>T p.V236= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99356092; called by muse, mutect2, varscan2
- KCNK7 | c.756A>G p.A252= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, varscan2
- MEIS2 | c.1386T>C p.S462= | Silent (SNP) | VAF 51/375 reads (14%) | catalogued as COSV99577336; called by muse, mutect2, varscan2
- MSX1 | c.744G>A p.P248= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1299510454, COSV101235764; called by muse, mutect2, varscan2
- MUC4 | c.1041T>C p.V347= | Silent (SNP) | VAF 12/337 reads (4%) | catalogued as COSV100642280; called by muse, mutect2
- PRCC | c.1473C>T p.F491= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99618925; called by muse, mutect2, varscan2
- PSMC1 | c.306G>C p.L102= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs1478325175, COSV99728559; called by muse, mutect2, varscan2
- RC3H1 | c.171C>A p.I57= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99281768; called by muse, mutect2
- SHOX2 | c.360G>C p.L120= (on ENST00000441443 / NM_006884.3; = p.L144= on NM_003030.4) | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV101273836; called by muse, mutect2
- TLR3 | c.1317C>T p.G439= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99711229; called by mutect2, varscan2
- TRABD2A | c.1233G>A p.T411= (on ENST00000409520 / NM_001277053.2; = p.T362= on NM_001080824.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs774323814, COSV52878560; called by muse, mutect2, varscan2
- TANK | c.*5_*6dup | 3'UTR (INS) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
